Somatic mutation profile of tumor specimen TCGA-QR-A70K-01A (aliquot TCGA-QR-A70K-01A-12D-A35D-08) from TCGA case TCGA-QR-A70K, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 61.7 years (22,519 days).
Specimen TCGA-QR-A70K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 39336717-2c61-4ebd-8f69-3f55704b682b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70K-10A (Blood Derived Normal), aliquot TCGA-QR-A70K-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c2623eb-7189-4d1f-bca1-5ae3cbe9ea8a

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 19, Silent 4, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCAF11 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV58110738; called by muse, mutect2, varscan2
- HECA | c.1162C>T p.L388F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200417003; called by muse, mutect2, varscan2
- KLRD1 | c.82G>T p.G28* | Nonsense Mutation (SNP) | VAF 19/90 reads (21%) | catalogued as COSV100282148; called by muse, mutect2, varscan2
- MLLT6 | c.3251A>G p.K1084R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs145698748; called by muse, mutect2, varscan2
- POLR3B | c.3137G>A p.R1046H | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57277495; called by muse, mutect2
- PYGB | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs770376445, COSV53818195; called by muse, mutect2, varscan2
- TPO | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs749399164; called by muse, mutect2, varscan2
- TRIP11 | c.4037A>G p.Q1346R | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs200785955; called by muse, mutect2, varscan2
- VPS13C | c.3815A>G p.H1272R (on ENST00000644861 / NM_020821.3; = p.H1229R on NM_017684.5) | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs754148788; called by muse, mutect2, varscan2
- AOC3 | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C5 | c.3556T>G p.F1186V | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- FAM83D | c.752T>A p.I251N | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.355); called by muse, mutect2
- FGF16 | c.329A>G p.D110G | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- HAT1 | c.841A>G p.S281G | Missense Mutation (SNP) | VAF 27/30 reads (90%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JOSD1 | c.340A>G p.N114D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR10X1 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.106); called by muse, mutect2
- OSBPL6 | c.2439G>T p.W813C | Missense Mutation (SNP) | VAF 49/61 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNASEK | c.155_159del p.A52Gfs*28 (on ENST00000548577; = p.A13Gfs*28 on NM_001004333.5) | Frame Shift Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- RTP4 | c.730A>G p.T244A | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNX19 | c.783C>G p.H261Q | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- THOC1 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CPSF4 | c.759C>T p.H253= | Silent (SNP) | VAF 16/42 reads (38%) | called by muse, mutect2, varscan2
- PIGO | c.1515G>A p.E505= | Silent (SNP) | VAF 11/63 reads (17%) | called by muse, mutect2, varscan2
- PROM1 | c.2124A>T p.G708= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as rs1267688102; called by muse, mutect2, varscan2
- SIMC1 | c.2328G>C p.L776= (on ENST00000443967 / NM_001308196.1; = p.L361= on NM_198567.5) | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as rs370669736; called by muse, mutect2, varscan2
